Gene-level copy-number profile of tumor specimen ALCH-B2QJ-TTP1-A from ALCHEMIST case ALCH-B2QJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.8 years (24,778 days).
Specimen ALCH-B2QJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c6c56dd8-94ac-4727-a68e-0d0010631b2f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2QJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/4a3cd97e-2cdd-40cb-a4e7-a9e37708c893

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 330; copy number 2: 15,713; copy number 3: 14,058; copy number 4: 22,662; copy number 5: 3,196; copy number 6: 1,091; copy number 7: 84; copy number 8: 101; copy number 9: 624; copy number 10: 34; copy number 11: 432; copy number 13: 62; copy number 14: 6; copy number 15: 159; copy number 17: 223; copy number 18: 46; copy number 19: 5; copy number 21: 6; copy number 23: 4; copy number 26: 13; copy number 27: 1; copy number 30: 12; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,729,570, 6 genes: AC239859.1, NBPF17P, PFN1P12, RNVU1-17, RNVU1-23, RNVU1-18.
- chr1:143,766,540–143,769,083, 1 gene: FAM91A3P.
- chr4:25,598,564–25,598,625, 1 gene: RNU7-126P.
- chr9:64,810,865–64,811,429, 1 gene: BNIP3P4.
- chr19:54,906,148–54,916,140, 1 gene: NCR1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,630 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,554–36,081, 1 gene, copy number 11: FAM138A.
- chr1:65,419–268,655, 9 genes, copy number 9–50: OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, RNU6-1100P, AP006222.2.
- chr2:196,833,004–196,927,796, 1 gene, copy number 9: PGAP1.
- chr3:167,864,773–198,123,232, 591 genes, copy number 11–30 (broad region; genes not listed).
- chr9:136,969,243–136,971,990, 1 gene, copy number 9: LINC02692.
- chr9:136,992,422–136,993,984, 1 gene, copy number 9: PAXX.
- chr11:69,809,968–71,818,238, 56 genes, copy number 10–17 (within-gene range 8–17): FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P, DHCR7, AP002387.1, NADSYN1, MIR6754, AP000867.2, KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1, KRTAP5-11, KRTAP5-14P, OR7E87P, UNC93B6, OR7E4P, AP000867.3, RPS3AP41, ALG1L9P, SNRPCP14, AP003498.1, ENPP7P8, AP003498.2.
- chr15:23,912,411–28,859,007, 173 genes, copy number 9–27 (broad region; genes not listed).
- chr19:28,065,267–40,465,764, 463 genes, copy number 9–26 (broad region; genes not listed).
- chr20:87,250–18,113,579, 333 genes, copy number 9–11 (broad region; genes not listed).
- chr20:18,137,863–18,143,169, 1 gene, copy number 11 (within-gene range 6–11): PET117.

Autosomal genes at a single copy (total copy number 1): 322. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
